Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3WY, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3WY-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Reformatted Report

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Other Related Data:

Billing Type:

INPATIENT

Financial Number:

100-0-3

Carcinoma, urothelial, NOS
812013

Clinical Diagnosis & History:

-year-old with muscle invasive bladder cancer.

Site: bladder, dome

C67.1 62312
KO

Specimens Submitted:

- 1: SP: Right distal ureter (fs)
- 2: SP: Left distal ureter (fs)
- 3: SP: Urethral margin (fs)
- 4: SP: Bladder, uterus, and ovaries
- 5: SP: Extended lymph node pocket
- 6: SP: Right common iliac lymph node
- 7: SP: Left common iliac lymph node
- 8: SP: Right distal lymph node
- 9: SP: Distal left lymph node
- 10: SP: Left presciatic fat
- 11: SP: Right presciatic fat
- 12: SP: Proximal left ureter
- 13: SP: Right ureter

DIAGNOSIS:

- 1) URETER, RIGHT DISTAL; BIOPSY:
- BENIGN URETER.
- 2) URETER, LEFT DISTAL; BIOPSY:
- BENIGN URETER.
- 3) URETHRAL MARGIN; BIOPSY:
- BENIGN URETHRAL TISSUE WITH SQUAMOUS LINING.
- 4) BLADDER, UTERUS, BILATERAL TUBES AND OVARIES; EXCISION:
- INVASIVE HIGH GRADE UROTHELIAL CARCINOMA. NO EVIDENCE OF TUMOR MULTICENTRICITY IS IDENTIFIED. NO IN SITU CARCINOMA IS IDENTIFIED. THE TUMOR INVADES INTO THE PERIVESICAL SOFT TISSUES. THE TUMOR DOES NOT EXTEND BEYOND THE BLADDER. NO VASCULAR INVASION IS IDENTIFIED. NO PERINEURAL INVASION IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC BLADDER MUCOSA IS UNREMARKABLE.
- THE UTERUS SHOWS ATROPHIC ENDOMETRIUM, A SINGLE 1.2 CM HYALINIZED LEIOMYOMA AND UNREMARKABLE CERVIX.
- UNREMARKABLE BILATERAL FALLOPIAN TUBES AND OVARIES.

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

- 5) LYMPH NODE, EXTENDED POCKET; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
- 6) LYMPH NODE, RIGHT COMMON ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODE, LEFT COMMON ILIAC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 8) LYMPH NODE, RIGHT DISTAL; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
- 9) LYMPH NODE, LEFT DISTAL; EXCISION:
- NINE BENIGN LYMPH NODES (0/9).
- 10) PRESACRIC FAT, LEFT; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 11) PRESACRIC FAT, RIGHT; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 12) URETER, LEFT PROXIMAL; BIOPSY:
- BENIGN URETER.
- 13) URETER, RIGHT; BIOPSY:
- BENIGN URETER.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section diagnosis, and is labeled "Right distal ureter". It consists of a fragment of ureter with surrounding fatty tissue measuring 0.9 x 0.8 x 0.6 cm. The entire specimen is submitted for frozen section diagnosis.

Summary of sections
FSC - frozen section control

2) The specimen is received fresh for frozen section diagnosis, and is labeled "Left distal ureter". It consists of a fragment of ureter with surrounding fatty tissue measuring 0.8 x 0.6 x 0.6 cm. The entire specimen is submitted for frozen section diagnosis.

Summary of sections
FSC - frozen section control

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

3) The specimen is received fresh for frozen section diagnosis, and is labeled "Urethral margin". It consists of a fragment of tan tissue measuring 1.8 x 0.2 x 0.2 cm. The entire specimen is submitted for frozen section diagnosis.

Summary of sections

FSC - frozen section control

4) The specimen is received fresh, labeled "Bladder, uterus and ovaries". It consists of a uterus measuring 8.0 cm from fundus to cervix, 5.0 cm intercornually and 2.5 cm from anterior to posterior. There are right and left, grossly unremarkable ovaries and fallopian tubes. The right ovary measures 2.5 x 0.9 x 0.7 cm, and the right fallopian tube measures 7.5 cm in length and 0.5 cm in diameter. The left ovary measures 2.1 x 1.3 x 0.8 cm, and the left fallopian tube measures 8.0 cm in length and 0.4 cm in diameter. The serosal surface of the uterus is pink-tan, smooth and shiny. The ectocervix is light tan, smooth and shiny. On opening, the cavity shows atrophic endometrium and a cavity measuring 3.5 x 1.8 cm. Serial sectioning reveals an intramural leiomyoma on the posterior wall of the uterus which measures 1.2 x 0.9 x 0.8 cm.

The posterior wall of the bladder is partially covered by peritoneum. Centrally the peritoneal surface is bumpy and ovary an area mass 1.0 x 0.8 cm. The right ureter measures 5.5 cm in length and 0.3 cm in diameter. The left ureter measures 4.5 cm in length and 0.3 cm in diameter. Both ureters are probe patent. The ureters are opened to reveal a light tan, smooth and shiny inner surface. On opening, the bladder shows an irregular, ulcerated lesion measuring 3.5 x 2.5 x 1.5 cm. This lesion is centered on the dome and extends to the right lateral and posterior walls of the bladder. The cut surface of the lesion shows focal necrosis. The tumor focally invades into perivesicle fat. The rest of the bladder mucosa is pink-tan and edematous. There are no lymph nodes grossly identified. Representative sections are submitted.

Summary of sections

UM - ureteral margin

RU - right ureter

LU - left ureter

RO - right orifice

LO - left orifice

TAC - trigone with anterior cervix

RW - right lateral wall of the bladder

LW - left lateral wall of the bladder

PW - posterior wall of the bladder

AW - anterior wall of the bladder

D - dome

T - lesion area in bladder

AC - anterior cervix

PC - posterior cervix

AU - anterior wall of the uterus

PU - posterior wall of the uterus

PUL - posterior wall of the uterus with leiomyoma

ROT - right ovary and fallopian tube

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

LOT - left ovary and fallopian tube

--

5) The specimen is received in formalin, labeled "Extended lymph node pocket". It consists of two irregular pieces of yellow-tan fibroadipose with possibly contains lymph nodes. The specimen measures in aggregate 2.5 x 2.5 x 0.5 cm. The entire specimen is submitted.

Summary of sections
U - undesignated

6) The specimen is received in formalin, labeled "Right common iliac lymph node". It consists of one lymph node surrounded by yellow-tan fibroadipose tissue measuring 4.0 x 1.0 x 0.8 cm. The specimen is bisected and entirely submitted.

Summary of sections
U - undesignated

7) The specimen is received in formalin, labeled "Left common iliac lymph node". It consists of an irregular piece of yellow-tan fibroadipose tissue measuring 2.3 x 1.9 x 0.5 cm which possible contains lymph nodes. The entire specimen is submitted.

Summary of sections
U - undesignated

8) The specimen is received in formalin, labeled "Right distal lymph node". It consists of multiple irregular pieces of yellow-tan fibroadipose tissue measuring in aggregate 5.0 x 3.2 x 1.7 cm. Approximately four lymph nodes are identified. The largest lymph node measures 2.3 x 1.2 x 0.6 cm. The lymph nodes are entirely submitted.

Summary of sections
U - undesignated

9) The specimen is received in formalin, labeled "Distal left lymph nodes". It consists of multiple irregular pieces of yellow-tan fibroadipose tissue measuring in aggregate 6.0 x 4.5 x 1.6 cm containing six lymph nodes. The largest lymph node measures 2.5 x 1.3 x 0.7 cm. The lymph nodes are entirely submitted.

Summary of sections
U - undesignated

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

10) The specimen is received in formalin, labeled "Pre-sciatic fat, left". It consists of multiple irregular pieces of yellow-tan fibroadipose tissue measuring in aggregate 1.8 x 1.3 x 0.5 cm. The entire specimen is submitted.

Summary of sections

U - undesignated

11) The specimen is received in formalin, labeled "Pre-sciatic fat, right". It consists of multiple irregular pieces of yellow-tan fibroadipose tissue measuring in aggregate 1.4 x 1.2 x 0.4 cm. The entire specimen is submitted.

Summary of sections

U - undesignated

12) The specimen is received in formalin, labeled "Proximal left ureter". It consists of a portion of ureter with attached yellow-tan fibroadipose tissue measuring 1.2 x 0.7 x 0.3 cm. The entire specimen is submitted.

Summary of sections

U - undesignated

13) The specimen is received in formalin, labeled "Right ureter". It consists of a portion of ureter which is partially surrounded by fibroadipose tissue measuring 1.1 x 0.7 x 0.4 cm. The entire specimen is submitted.

Summary of sections

U - undesignated

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	FSC		1	1	Y
2	FSC		1	1	Y
3	FSC		1	1	Y
4	AC		1	1	N
	AU		1	1	
	AW		1	1	
	D		1	1	
	LO		1	1	
	LOT		1	M	
	LU		1	1	
	LW		1	1	
	PC		1	1	
	PU		1	1	
	PUL		1	1	
	PW		1	1	
	RO		1	1	
	ROT		1	M	
	RU		1	1	
	RW		1	1	
	T		3	3	

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

	TAC	1	1	
	UM	1	2	
5	U	2	M	Y
6	U	2	M	Y
7	U	1	M	Y
8	U	4	M	Y
9	U	5	M	Y
10	U	1	M	Y
11	U	1	M	Y
12	U	1	1	Y
13	U	1	2	Y

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: NEGATIVE FOR TUMOR
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: NEGATIVE FOR TUMOR (
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS: NEGATIVE FOR CARCINOMA.
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 31bb2d04-5b79-43ed-ac78-f759990fedf7 (TCGA-DK-A3WY.62654E3C-3796-43B4-A347-FF4C22EEE143.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).